Gene-level copy-number profile of tumor specimen TCGA-D7-6818-01A from TCGA case TCGA-D7-6818, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 53.1 years (19,391 days).
Specimen TCGA-D7-6818-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.a51fea9a-d134-46ea-8e20-038ade8438d6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-6818-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8fc1120b-b217-46d7-8cbe-81fcf320d50a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 2,261; copy number 2: 36,354; copy number 3: 16,794; copy number 4: 3,517; copy number 5: 207; copy number 6: 630; copy number 7: 21; copy number 17: 7; copy number 32: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-6818-01A-11D-1881-01): tumor purity 0.43, ploidy 2.37, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr13:19,345,049–19,536,762, 7 genes (within-gene range 0–3): LINC00421, PARP4P2, CCNQP3, AL356259.1, SLC25A15P2, TPTE2, CYCSP32.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 877 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,391,313–234,970,062, 21 genes, copy number 7 (within-gene range 3–7): TARBP1, LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2.
- chr5:17,511,833–54,872,551, 458 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr7:22,298,594–22,727,613, 5 genes, copy number 5 (within-gene range 3–5): RNA5SP227, STEAP1B, EEF1A1P6, AC002480.1, AC002480.2.
- chr13:92,339,794–114,337,626, 333 genes, copy number 5–6 (broad region; genes not listed).
- chr19:27,638,483–30,038,181, 60 genes, copy number 6–32: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1.

Autosomal genes at a single copy (total copy number 1): 2,261. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
